Somatic mutation profile of tumor specimen TCGA-BA-4075-01A (aliquot TCGA-BA-4075-01A-01D-1434-08) from TCGA case TCGA-BA-4075, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 49.1 years (17,951 days).
Specimen TCGA-BA-4075-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20e4fcea-202d-4f56-80ce-3b2298d201b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-4075-10A (Blood Derived Normal), aliquot TCGA-BA-4075-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ab093d4-1b67-448d-9254-323f48d0c6c7

The open-access MAF lists 156 somatic variants for this specimen: 110 protein-altering or splice-affecting, 39 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 39, Nonsense Mutation 5, Splice Site 5, Intron 3, Frame Shift Del 3, Frame Shift Ins 2, 5'Flank 2, Splice Region 1, 5'UTR 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-2A>T p.X51_splice | Splice Site (SNP) | VAF 7/13 reads (54%) | hotspot (GDC flag); catalogued as CS014762, CS127043, COSV58692638, COSV58692823, COSV58707376; called by muse, mutect2, varscan2
- TP53 | c.919+2T>G p.X307_splice | Splice Site (SNP) | VAF 137/211 reads (65%) | hotspot (GDC flag); catalogued as rs1131691016, COSV52698436, COSV52737448, COSV52774697; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1236G>C p.Q412H | Missense Mutation (SNP) | VAF 8/207 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99686202; called by muse, mutect2
- ADGRA1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1050948945, COSV101192716; called by muse, mutect2, varscan2
- ADRA1A | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 18/315 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99371369; called by muse, mutect2
- ARAP3 | c.2824C>T p.R942W | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749687917, COSV53351392; called by muse, mutect2, varscan2
- ASIC5 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.08); catalogued as COSV101611148; called by muse, mutect2
- ASXL3 | c.3365A>G p.Q1122R | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as COSV99325472; called by muse, mutect2
- ATP2C2 | c.2290A>G p.I764V | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99298309; called by muse, mutect2, varscan2
- ATR | c.1939A>C p.I647L | Missense Mutation (SNP) | VAF 117/319 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100638354; called by muse, mutect2, varscan2
- BST1 | c.433C>G p.R145G | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV99400028; called by muse, mutect2, varscan2
- C1GALT1 | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 112/168 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs369665733; called by muse, mutect2, varscan2
- CARD11 | c.2650C>T p.R884W | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1450077193, COSV62753782; called by muse, mutect2, varscan2
- CNTNAP2 | c.1809A>T p.K603N | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV100662752, COSV100667936; called by muse, mutect2, varscan2
- COL5A2 | c.2632C>A p.Q878K | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.973); catalogued as COSV100880538; called by muse, mutect2
- COPG2 | c.737+1G>T p.X246_splice | Splice Site (SNP) | VAF 9/153 reads (6%) | catalogued as COSV100449675; called by muse, mutect2
- COPG2 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV100449676; called by muse, mutect2
- CYB561A3 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs375115347; called by muse, mutect2, varscan2
- DCAF12L2 | c.1079A>T p.Q360L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV100758675; called by muse, mutect2
- DCAF12L2 | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV100758676; called by muse, mutect2
- DENND4C | c.1183A>T p.T395S | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV100991432; called by muse, mutect2
- DNAH10 | c.3207G>A p.M1069I (on ENST00000409039; = p.M1008I on NM_207437.3) | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV101292357; called by muse, mutect2
- DNAH3 | c.6082C>T p.Q2028* | Nonsense Mutation (SNP) | VAF 72/299 reads (24%) | catalogued as rs763244200, COSV99768577; called by muse, mutect2, varscan2
- ECHS1 | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759771909, COSV100881915; called by muse, mutect2, varscan2
- EDRF1 | c.2911T>G p.Y971D (on ENST00000356792 / NM_001202438.2; = p.Y937D on NM_015608.2) | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100523624; called by muse, mutect2, varscan2
- EGF | c.1654G>T p.E552* | Nonsense Mutation (SNP) | VAF 8/138 reads (6%) | catalogued as COSV99491117; called by muse, mutect2
- EP300 | c.2419A>G p.I807V | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.035); catalogued as rs201054979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EXO1 | c.1088A>C p.K363T | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV100799951; called by muse, mutect2
- FABP3 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 110/394 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1181172241, COSV100704059; called by muse, mutect2, varscan2
- FGD4 | c.1558A>G p.I520V | Missense Mutation (SNP) | VAF 128/261 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs775237819, COSV99847290; called by muse, mutect2, varscan2
- FMO4 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as COSV100882083; called by muse, varscan2
- FZD1 | c.377A>T p.D126V | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99842618; called by muse, mutect2, varscan2
- GABRG3 | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100408284; called by muse, mutect2
- GAS6 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as COSV100581818; called by muse, mutect2
- GCAT | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs754057883, COSV99959845; called by muse, mutect2
- GCM2 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV101069549; called by muse, mutect2
- GK2 | c.1286C>A p.T429N | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725991; called by muse, mutect2, varscan2
- GLP2R | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 104/332 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459375359, COSV99302196; called by muse, mutect2, varscan2
- GON4L | c.2300G>A p.S767N | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99674878; called by muse, mutect2, varscan2
- GPR15 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.309); catalogued as COSV99423830; called by muse, mutect2
- HAPLN2 | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99660983; called by muse, mutect2, varscan2
- LARS2 | c.728T>G p.I243S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV99647971; called by muse, mutect2, varscan2
- LRIF1 | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100870871; called by muse, mutect2, varscan2
- LUC7L3 | c.752A>T p.K251M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV99536995; called by muse, mutect2
- MDM2 | c.1336A>G p.I446V | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99254691; called by muse, mutect2
- MICU1 | c.851G>A p.G284E (on ENST00000361114 / NM_001195518.2; = p.G290E on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100741825; called by muse, mutect2, varscan2
- MLXIPL | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.921); catalogued as rs782442244; called by muse, mutect2
- MYO16 | c.5099-1G>C p.X1700_splice | Splice Site (SNP) | VAF 26/83 reads (31%) | catalogued as COSV100696833; called by muse, mutect2, varscan2
- NCBP1 | c.2341G>A p.V781M | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs377264051; called by muse, varscan2
- NDUFA12 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100580876; called by muse, mutect2
- NOTCH1 | c.1346G>A p.C449Y | Missense Mutation (SNP) | VAF 86/118 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489772494, COSV99489494; called by muse, mutect2, varscan2
- NR4A3 | c.1265C>G p.T422S | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100432545; called by muse, mutect2, varscan2
- NUP160 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101021542; called by muse, mutect2
- OR5P3 | c.338T>A p.F113Y | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as COSV100103172; called by muse, mutect2
- OR6F1 | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV100129289; called by muse, mutect2
- PCDH15 | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 39/364 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV100223065; called by muse, mutect2, varscan2
- PCDHA11 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.16); catalogued as rs991131905, COSV56499175; called by muse, mutect2
- PCDHGB5 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); catalogued as COSV54003416; called by muse, mutect2
- PCLO | c.6248C>A p.T2083N | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV100434142, COSV61628466; called by muse, mutect2
- PIBF1 | c.1382A>T p.K461I | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100411673; called by muse, mutect2, varscan2
- PKD1L1 | c.2277G>T p.Q759H | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99220413; called by muse, mutect2, varscan2
- POU2F1 | c.2036C>T p.P679L (on ENST00000541643 / NM_001365848.1; = p.P702L on NM_002697.4) | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54825329; called by muse, mutect2
- PPP2CB | c.268G>T p.G90* | Nonsense Mutation (SNP) | VAF 13/297 reads (4%) | catalogued as COSV99646673; called by muse, mutect2
- PRMT3 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 91/214 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs142076035; called by muse, mutect2, varscan2
- PSD3 | c.2662G>A p.G888R (on ENST00000440756; = p.G887R on NM_015310.4) | Missense Mutation (SNP) | VAF 23/359 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV99676315; called by muse, mutect2
- RBIS | c.197A>T p.K66I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV99809600; called by muse, mutect2, varscan2
- RBM19 | c.2385+1G>T p.X795_splice | Splice Site (SNP) | VAF 30/516 reads (6%) | catalogued as COSV99926346; called by muse, mutect2
- RBM26 | c.2629G>T p.G877W (on ENST00000438737 / NM_001366735.2; = p.G850W on NM_022118.5) | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57393605, COSV99936281; called by muse, mutect2
- RIF1 | c.6752A>G p.N2251S | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.352); catalogued as COSV99690780; called by muse, mutect2, varscan2
- RNF213 | c.11855T>A p.V3952D | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100301000; called by muse, mutect2, varscan2
- RRAGC | c.362T>G p.M121R | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV100883839; called by muse, mutect2, varscan2
- RTP2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779097861, COSV100832966, COSV64079165; called by muse, mutect2, varscan2
- SERPINB4 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100345810; called by muse, mutect2
- SH3KBP1 | c.1903A>C p.K635Q | Missense Mutation (SNP) | VAF 63/90 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV101116264; called by muse, mutect2, varscan2
- SIL1 | c.653A>G p.N218S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150156151; called by muse, mutect2, varscan2
- SLC19A3 | c.1105A>G p.I369V | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV99295935; called by muse, mutect2
- SNW1 | c.1115C>A p.A372E | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.986); catalogued as COSV99834421; called by muse, mutect2, varscan2
- SUGCT | c.894G>T p.L298F | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100002813; called by muse, mutect2, varscan2
- SYNE1 | c.23102C>T p.P7701L (on ENST00000367255 / NM_182961.4; = p.P7630L on NM_033071.3) | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780201995; called by muse, mutect2, varscan2
- TGFBR3 | c.2101C>T p.L701F | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99283250; called by muse, mutect2, varscan2
- TMEM53 | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs1455585451, COSV100132156; called by muse, mutect2, varscan2
- TMEM53 | c.795C>A p.S265R | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs763564702, COSV100132157; called by muse, mutect2, varscan2
- TMEM63C | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 6/190 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV100029538; called by muse, mutect2
- TNPO1 | c.1706A>G p.Y569C | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV100473664; called by muse, mutect2, varscan2
- TRPV5 | c.39C>A p.S13R | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.113); catalogued as COSV99520694; called by muse, mutect2
- TSR1 | c.1607C>G p.T536S | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as rs753419625, COSV100027101; called by muse, mutect2
- TTC19 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99250636; called by muse, mutect2, varscan2
- UGT2B4 | c.634A>G p.K212E | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as COSV100522499; called by muse, mutect2, varscan2
- VEZT | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs550777059, COSV99703517, COSV99704061; called by muse, mutect2
- WDR89 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 56/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50826605; called by muse, mutect2, varscan2
- WDR91 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.035); catalogued as COSV100615759; called by muse, mutect2
- WHRN | c.1167G>T p.G389= | Splice Region (SNP) | VAF 8/243 reads (3%) | catalogued as COSV99470393; called by muse, mutect2
- XIRP2 | c.2536T>G p.F846V (on ENST00000628543; = p.F1021V on NM_152381.6) | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99744597; called by muse, mutect2
- XIRP2 | c.7696C>A p.Q2566K (on ENST00000628543; = p.Q2741K on NM_152381.6) | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV54690694, COSV99744598; called by muse, mutect2
- XXYLT1 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.033); catalogued as COSV100118562; called by muse, mutect2
- YIPF7 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV60656727, COSV60657595; called by muse, mutect2
- ZEB2 | c.1241C>A p.P414H | Missense Mutation (SNP) | VAF 6/162 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.707); catalogued as COSV100356376; called by muse, mutect2
- ZNF19 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs199884411, COSV99867504; called by muse, mutect2, varscan2
- ZNF493 | c.1272A>T p.K424N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100828764; called by muse, mutect2, varscan2
- ZNF648 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 69/117 reads (59%) | catalogued as rs1427227568, COSV100374554; called by muse, mutect2, varscan2
- ZNF75D | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs782023281, COSV100883668; called by muse, mutect2, varscan2
- ZPR1 | c.1039C>T p.L347F | Missense Mutation (SNP) | VAF 132/181 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs1007881153, COSV99911369; called by muse, mutect2, varscan2
- FAT1 | c.5652dup p.E1885* | Frame Shift Ins (INS) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- FAT3 | c.10136_10145del p.S3379Lfs*10 | Frame Shift Del (DEL) | VAF 14/133 reads (11%) | called by mutect2, pindel
- KCNAB3 | c.532dup p.I178Nfs*2 | Frame Shift Ins (INS) | VAF 77/697 reads (11%) | called by mutect2, pindel, varscan2
- KRT5 | c.1582_1587del p.S528_S529del | In Frame Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- NAT8 | c.38A>G p.D13G | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUP50 | c.1175del p.Q392Rfs*10 | Frame Shift Del (DEL) | VAF 33/127 reads (26%) | called by mutect2, pindel, varscan2
- SUN2 | c.705del p.Y236Mfs*88 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- TERF2 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 9/252 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.319); called by muse, mutect2
- ADAMTS13 | c.4125G>A p.Q1375= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV99390358; called by muse, mutect2
- ARID5A | c.1737C>A p.V579= | Silent (SNP) | VAF 39/188 reads (21%) | catalogued as COSV100673618; called by muse, mutect2, varscan2
- CFAP91 | c.1527G>A p.Q509= | Silent (SNP) | VAF 27/255 reads (11%) | catalogued as rs779317877, COSV99847248; called by muse, mutect2, varscan2
- CHD7 | c.8682C>T p.L2894= | Silent (SNP) | VAF 30/158 reads (19%) | catalogued as rs780047697, COSV101418313; called by muse, mutect2, varscan2
- CLDN17 | c.60G>A p.G20= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as COSV99729271; called by muse, mutect2, varscan2
- EGFL7 | c.99C>T p.V33= | Silent (SNP) | VAF 14/202 reads (7%) | catalogued as COSV100452014; called by muse, mutect2
- EMILIN3 | c.2193G>A p.L731= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV100182661; called by muse, mutect2, varscan2
- ESRRG | c.288T>A p.P96= | Silent (SNP) | VAF 20/258 reads (8%) | catalogued as COSV100753311; called by muse, mutect2
- FAM120C | c.456G>C p.A152= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100070229, COSV100070577; called by muse, mutect2
- FARP1 | c.861G>A p.A287= | Silent (SNP) | VAF 34/333 reads (10%) | catalogued as rs747125925, COSV100131205; called by muse, mutect2
- FASTKD5 | c.876T>G p.R292= | Silent (SNP) | VAF 15/188 reads (8%) | catalogued as COSV99418180; called by muse, mutect2
- FBXL2 | c.1221A>G p.T407= | Silent (SNP) | VAF 14/278 reads (5%) | catalogued as COSV99372064; called by muse, mutect2
- FLT3 | c.2232G>A p.Q744= | Silent (SNP) | VAF 153/280 reads (55%) | catalogued as COSV99609340; called by muse, mutect2, varscan2
- GLDN | c.1371C>T p.F457= | Silent (SNP) | VAF 13/178 reads (7%) | catalogued as COSV100117810; called by muse, mutect2
- GPR61 | c.1179G>A p.E393= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV100879913; called by muse, mutect2, varscan2
- HGD | c.588C>T p.T196= | Silent (SNP) | VAF 109/177 reads (62%) | catalogued as CD002908, COSV99381149; called by muse, mutect2, varscan2
- LMOD1 | c.1608C>T p.P536= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100939209; called by muse, mutect2
- NAA20 | c.390A>T p.V130= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV100131724; called by muse, mutect2, varscan2
- NOD1 | c.738C>T p.D246= | Silent (SNP) | VAF 13/389 reads (3%) | catalogued as COSV99768253; called by muse, mutect2
- OLFML2A | c.1644C>T p.I548= | Silent (SNP) | VAF 54/103 reads (52%) | catalogued as COSV56583021; called by muse, mutect2, varscan2
- OR13F1 | c.684C>A p.I228= | Silent (SNP) | VAF 155/327 reads (47%) | catalogued as COSV58252898; called by muse, mutect2, varscan2
- OR5L2 | c.498C>A p.I166= | Silent (SNP) | VAF 16/482 reads (3%) | catalogued as COSV65724406, COSV65725288; called by muse, mutect2
- OXER1 | c.234C>T p.S78= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV99685442; called by muse, mutect2, varscan2
- PAN3 | c.2212A>C p.R738= | Silent (SNP) | VAF 97/189 reads (51%) | catalogued as COSV99144943; called by muse, mutect2, varscan2
- PSG3 | c.570T>A p.T190= | Silent (SNP) | VAF 132/457 reads (29%) | catalogued as rs970095084, COSV100549088; called by muse, mutect2, varscan2
- RAPGEFL1 | c.741A>G p.L247= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99229080; called by muse, mutect2
- RNF14 | c.669T>C p.C223= | Silent (SNP) | VAF 51/148 reads (34%) | catalogued as COSV100641255; called by muse, mutect2, varscan2
- RNF213 | c.11856C>T p.V3952= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV100301001; called by muse, mutect2, varscan2
- SASH1 | c.2691C>T p.S897= | Silent (SNP) | VAF 11/309 reads (4%) | catalogued as COSV100821279; called by muse, mutect2
- SLC11A2 | c.93G>A p.V31= (on ENST00000394904 / NM_001379455.1; = p.V2= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100014880; called by muse, mutect2, varscan2
- SLITRK5 | c.141C>A p.I47= | Silent (SNP) | VAF 101/232 reads (44%) | catalogued as COSV100280925, COSV61523495; called by muse, mutect2, varscan2
- SMARCC2 | c.1692A>G p.K564= | Silent (SNP) | VAF 63/217 reads (29%) | catalogued as COSV99911538; called by muse, mutect2, varscan2
- SYNRG | c.2013A>T p.G671= | Silent (SNP) | VAF 69/110 reads (63%) | called by muse, mutect2, varscan2
- TGFBR3 | c.2100G>T p.L700= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV99283251; called by muse, mutect2, varscan2
- TMOD4 | c.216G>A p.L72= | Silent (SNP) | VAF 77/386 reads (20%) | catalogued as COSV99766102; called by muse, mutect2, varscan2
- TNRC6B | c.666G>A p.S222= | Silent (SNP) | VAF 57/167 reads (34%) | catalogued as rs199953986, COSV100109957; called by muse, mutect2, varscan2
- USP48 | c.2907T>C p.A969= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV100380007; called by muse, mutect2, varscan2
- WASHC2A | c.798G>A p.E266= | Silent (SNP) | VAF 50/180 reads (28%) | called by muse, mutect2, varscan2
- ZFHX4 | c.9330C>T p.P3110= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as rs771817655, COSV51493110, COSV99264524; called by muse, mutect2
- AP000769.3 | chr11:65503558 A>G | 5'Flank (SNP) | VAF 42/202 reads (21%) | catalogued as rs748495766; called by muse, mutect2, varscan2
- CBLN3 | chr14:24430818 C>T | 5'Flank (SNP) | VAF 9/24 reads (38%) | catalogued as rs1389653865, COSV99249846; called by muse, mutect2, varscan2
- DNMT3A | c.-178+13716G>A | Intron (SNP) | VAF 6/20 reads (30%) | catalogued as rs555760713, COSV99263141; called by muse, varscan2
- EGFR | c.1881-723C>T | Intron (SNP) | VAF 66/252 reads (26%) | catalogued as COSV99292713; called by muse, mutect2, varscan2
- LNX1 | c.380+15670C>T | Intron (SNP) | VAF 18/65 reads (28%) | catalogued as COSV55784299; called by muse, mutect2, varscan2
- PGAM1 | c.1dup p.M1Nfs*? | 5'UTR (INS) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- SNORD115-41 | n.59C>G | RNA (SNP) | VAF 76/486 reads (16%) | called by muse, mutect2, varscan2
